Somatic mutation profile of tumor specimen TCGA-E5-A2PC-01A (aliquot TCGA-E5-A2PC-01A-11D-A202-08) from TCGA case TCGA-E5-A2PC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.1 years (22,308 days).
Specimen TCGA-E5-A2PC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93b48470-3c24-42f7-af48-dbbedd96b06f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E5-A2PC-10A (Blood Derived Normal), aliquot TCGA-E5-A2PC-10B-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61500de2-0dd6-4f5e-80b4-d9f7b1abf5c0

The open-access MAF lists 265 somatic variants for this specimen: 191 protein-altering or splice-affecting, 65 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 65, Nonsense Mutation 9, Frame Shift Del 6, Intron 5, Splice Site 5, RNA 3, Splice Region 3, Translation Start Site 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FOXA1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 41/78 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1204900727, COSV51643222, COSV51643797; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 25/33 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TRIP12 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1553602821, COSV52260381; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV55287056; called by muse, mutect2, varscan2
- ABCC4 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV65310387; called by muse, mutect2, varscan2
- ABCC8 | c.2842del p.A948Pfs*94 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | catalogued as COSV56855906; called by mutect2, pindel, varscan2
- ABLIM1 | c.1028A>T p.E343V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53301647; called by muse, mutect2, varscan2
- ACOT2 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53149990; called by muse, mutect2, varscan2
- ADAMTS3 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54387007; called by muse, mutect2, varscan2
- ADAMTS8 | c.2393T>A p.F798Y | Missense Mutation (SNP) | VAF 120/158 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57296323; called by muse, mutect2, varscan2
- ANAPC1 | c.2537A>C p.Q846P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV61974649; called by muse, mutect2, varscan2
- AP4E1 | c.2454T>A p.F818L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55915567; called by muse, mutect2, varscan2
- APOBR | c.2779G>C p.E927Q (on ENST00000431282; = p.E936Q on NM_018690.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.251); catalogued as COSV60489200; called by muse, mutect2
- ARMH4 | c.885A>C p.E295D | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV50762359; called by muse, mutect2, varscan2
- ARMH4 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV50762374, COSV50766343; called by muse, mutect2, varscan2
- ASPM | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54136347; called by muse, mutect2, varscan2
- ATN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV63110414; called by muse, mutect2
- B3GNTL1 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57947539; called by muse, mutect2, varscan2
- BRWD1 | c.1751C>A p.P584H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60893495; called by muse, mutect2, varscan2
- CACNA1C | c.5023G>A p.A1675T | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.198); catalogued as rs773930851, COSV59702061; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CACNA1I | c.3582C>G p.I1194M | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV60803972, COSV60807173; called by muse, mutect2, varscan2
- CAST | c.1699C>A p.L567I (on ENST00000341926; = p.L650I on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57085812, COSV99701362; called by muse, mutect2, varscan2
- CC2D1A | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs764547752, COSV54308061; called by muse, mutect2, varscan2
- CCDC173 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.596); catalogued as COSV71653094; called by muse, mutect2, varscan2
- CCN5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as COSV51936503; called by muse, mutect2, varscan2
- CD300LG | c.76A>T p.S26C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53222899; called by muse, mutect2, varscan2
- CDC7 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV52309598; called by muse, mutect2, varscan2
- CDKL5 | c.2408C>A p.T803K | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.194); catalogued as COSV66110500; called by muse, mutect2, varscan2
- CELSR3 | c.5704C>A p.P1902T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as COSV50841644; called by muse, mutect2, varscan2
- CEP55 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV65184688; called by muse, mutect2, varscan2
- CHUK | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64917388, COSV64917418; called by muse, mutect2, varscan2
- CLEC3A | c.590G>C p.R197T (on ENST00000651443; = p.R188T on NM_005752.6) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as CM142342, COSV55220068; called by muse, mutect2, varscan2
- COBLL1 | c.2555C>G p.T852S (on ENST00000392717; = p.T814S on NM_014900.5) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV52064090; called by muse, mutect2, varscan2
- COL6A3 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55082344; called by muse, mutect2, varscan2
- COL7A1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV60401436; called by muse, mutect2, varscan2
- COL9A3 | c.1548G>C p.P516= | Splice Region (SNP) | VAF 31/80 reads (39%) | catalogued as COSV58983097, COSV58983447, COSV58987178; called by muse, mutect2, varscan2
- CSH2 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 85/209 reads (41%) | catalogued as COSV61080147; called by muse, mutect2, varscan2
- CUL7 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV54813917; called by muse, mutect2, varscan2
- CYP26B1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV50010967; called by muse, mutect2, varscan2
- DCST1 | c.2104A>G p.T702A | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55057150; called by muse, mutect2, varscan2
- DGKQ | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.596); catalogued as rs746018784; called by muse, mutect2, varscan2
- DMBT1 | c.6992C>T p.S2331L (on ENST00000338354 / NM_001377530.1; = p.S1574L on NM_004406.3) | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV57536988; called by muse, mutect2, varscan2
- DOCK2 | c.4091G>T p.R1364L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769663046, COSV56946543, COSV56987375; called by muse, mutect2, varscan2
- E2F7 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV59738085; called by muse, mutect2, varscan2
- EGFR | c.1151C>G p.T384S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV51779680; called by muse, mutect2, varscan2
- EIF2AK3 | c.1606A>G p.T536A | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57545655; called by muse, mutect2, varscan2
- EML2 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55603010; called by muse, mutect2, varscan2
- EML2 | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 23/126 reads (18%) | catalogued as COSV55603023; called by muse, mutect2, varscan2
- ENTHD1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57318000; called by muse, mutect2, varscan2
- ERCC2 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM950364, COSV67267039, COSV67269069; called by muse, mutect2, varscan2
- FAM124A | c.1484G>T p.R495L (on ENST00000322475 / NM_001242312.2; = p.R531L on NM_145019.4) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs758653958, COSV54474753; called by muse, mutect2, varscan2
- FGF12 | c.526G>T p.G176* (on ENST00000454309 / NM_021032.5; = p.G114* on NM_004113.6) | Nonsense Mutation (SNP) | VAF 34/184 reads (18%) | catalogued as COSV53156255; called by muse, mutect2, varscan2
- FOXP3 | c.1295G>C p.*432Sext*? | Nonstop Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV66050959; called by muse, mutect2, varscan2
- GAR1 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV56993074; called by muse, mutect2, varscan2
- GDF5 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs771055628, COSV65499127; called by muse, mutect2, varscan2
- GFUS | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV55308580; called by muse, mutect2
- GLI1 | c.2936A>G p.N979S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.024); catalogued as COSV57358925; called by muse, mutect2, varscan2
- GNAI1 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as COSV63522008; called by muse, mutect2, varscan2
- GNB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 136/273 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV66099885, COSV66100937; called by muse, mutect2, varscan2
- GON4L | c.3202T>C p.S1068P | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.424); catalogued as COSV55188662; called by muse, mutect2, varscan2
- GPATCH8 | c.4169C>T p.A1390V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59197479; called by muse, mutect2
- GPR19 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV60123058; called by muse, mutect2, varscan2
- HCN1 | c.819G>T p.R273S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV57497745; called by muse, mutect2, varscan2
- HPCAL4 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as rs1469875225; called by muse, mutect2, varscan2
- IGF2BP3 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV51681267, COSV51689764; called by muse, mutect2, varscan2
- IKBIP | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs768916963, COSV54488871; called by muse, mutect2, varscan2
- IKBKB | c.1088C>G p.P363R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs767388805, COSV100645558, COSV100645880, COSV60599207; called by muse, mutect2, varscan2
- IL17C | c.407A>C p.D136A | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54918198; called by muse, mutect2, varscan2
- INSM1 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760125360; called by muse, mutect2, varscan2
- ITSN1 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV66081590; called by muse, mutect2, varscan2
- JAKMIP1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs748319777, COSV51524090; called by muse, mutect2, varscan2
- KAT6A | c.3379C>G p.L1127V | Missense Mutation (SNP) | VAF 54/328 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV55903846, COSV99705945; called by muse, mutect2, varscan2
- KCNA2 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60369289; called by muse, mutect2, varscan2
- KDM3A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs760305076, COSV57224424; called by muse, mutect2, varscan2
- KDM6A | c.4074C>A p.C1358* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV65037872; called by muse, mutect2, varscan2
- KERA | c.143G>C p.C48S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57130123; called by muse, mutect2, varscan2
- KPNB1 | c.1765C>A p.Q589K | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV51595547; called by muse, mutect2, varscan2
- KTN1 | c.2035G>C p.D679H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV68022647; called by muse, mutect2, varscan2
- LANCL2 | c.762G>C p.W254C | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54648131; called by muse, mutect2, varscan2
- LAS1L | c.1996A>T p.M666L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56706586; called by muse, mutect2, varscan2
- LMX1A | c.1036A>T p.S346C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as rs771576895, COSV54218038; called by muse, mutect2
- LONP1 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140317309; called by muse, mutect2, varscan2
- LRP1 | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54504269; called by muse, mutect2, varscan2
- LRRC41 | c.2209C>G p.L737V | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58439171; called by muse, mutect2, varscan2
- LYST | c.331A>T p.N111Y | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.429); catalogued as COSV67704234; called by muse, mutect2, varscan2
- MAGEC2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.627); catalogued as COSV55998298; called by muse, mutect2, varscan2
- MAGEC2 | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 65/205 reads (32%) | catalogued as COSV55998309; called by muse, mutect2, varscan2
- MCM4 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs562067900, COSV50621666; called by muse, mutect2, varscan2
- MDH1B | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs375320635; called by muse, mutect2, varscan2
- MEP1B | c.2063C>A p.S688* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV52496122, COSV52499330; called by muse, mutect2
- MFN1 | c.841T>G p.F281V | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54938438; called by muse, mutect2, varscan2
- MMP19 | c.171G>T p.L57= | Splice Region (SNP) | VAF 25/100 reads (25%) | catalogued as COSV59450575; called by muse, mutect2, varscan2
- MTM1 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60334028; called by muse, mutect2, varscan2
- MTUS1 | c.2554C>G p.H852D | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as rs774888240, COSV50551793; called by muse, mutect2, varscan2
- MUSK | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51879707; called by muse, mutect2, varscan2
- MXRA5 | c.6923C>T p.T2308I | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54226989; called by muse, mutect2, varscan2
- MXRA5 | c.3958A>T p.T1320S | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV54227018; called by muse, mutect2, varscan2
- MYBL2 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV53828358; called by muse, mutect2, varscan2
- MYH3 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 131/188 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56861982; called by muse, mutect2, varscan2
- NAALADL2 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV69154127; called by muse, mutect2, varscan2
- NCAPG | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs1320965514, COSV52269032; called by muse, mutect2, varscan2
- NIF3L1 | c.807A>G p.I269M (on ENST00000409020 / NM_001369444.1; = p.I242M on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.844); catalogued as COSV62899968; called by muse, mutect2, varscan2
- NIN | c.3623T>A p.M1208K | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55382733; called by muse, mutect2, varscan2
- NLRP9 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV60460662; called by muse, mutect2, varscan2
- NRP2 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55924521; called by muse, mutect2, varscan2
- NT5C1B | c.1097T>A p.L366H (on ENST00000359846 / NM_001199086.2; = p.L306H on NM_033253.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58394762; called by muse, mutect2, varscan2
- OBSL1 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs545493745, COSV54709798; called by muse, mutect2
- OGT | c.2439C>A p.I813= | Splice Region (SNP) | VAF 18/42 reads (43%) | catalogued as COSV65479913; called by muse, mutect2, varscan2
- OPRPN | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV68193445; called by muse, mutect2, varscan2
- OR4A16 | c.60T>A p.D20E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59042201; called by muse, mutect2, varscan2
- OR5L2 | c.844A>T p.I282F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756549286, COSV65723544; called by muse, mutect2, varscan2
- OR8H1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs191885508, COSV57293032, COSV57293479; called by muse, mutect2, varscan2
- OSBPL3 | c.105G>C p.W35C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57653929; called by muse, mutect2, varscan2
- PARP12 | c.2042C>A p.S681Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.19); catalogued as COSV54936489; called by muse, mutect2, varscan2
- PBRM1 | c.3926T>C p.I1309T (on ENST00000296302 / NM_001366071.2; = p.I1284T on NM_018313.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV56264933; called by muse, mutect2, varscan2
- PIGG | c.1082T>A p.L361Q | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV56316666; called by muse, mutect2, varscan2
- PKP3 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58986260; called by muse, mutect2, varscan2
- PLIN4 | c.1354A>G p.K452E (on ENST00000301286; = p.K467E on NM_001367868.2) | Missense Mutation (SNP) | VAF 97/124 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1308354993, COSV56688249; called by muse, mutect2, varscan2
- PLK2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as COSV57106149, COSV57107028; called by muse, mutect2, varscan2
- PNCK | c.403C>T p.R135W (on ENST00000340888 / NM_001366975.1; = p.R218W on NM_001039582.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1557039999, COSV61742909; called by muse, mutect2, varscan2
- POLR2C | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV54672004; called by muse, mutect2, varscan2
- POU3F1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65948687; called by muse, mutect2, varscan2
- PRAMEF19 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 158/311 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs761221963, COSV101069365; called by muse, mutect2, varscan2
- PRKAR1B | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1229349513, COSV64317999; called by muse, mutect2, varscan2
- PRPF4 | c.1313G>T p.R438L (on ENST00000374198 / NM_001322267.2; = p.R439L on NM_004697.5) | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as COSV100950760, COSV65252347; called by muse, mutect2, varscan2
- QARS1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as COSV60274256; called by muse, mutect2, varscan2
- RANBP2 | c.5450C>T p.A1817V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51706722; called by muse, mutect2, varscan2
- RANGAP1 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62362644; called by muse, mutect2, varscan2
- RASGEF1B | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV52335977; called by muse, mutect2, varscan2
- RAX2 | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1404557350, COSV57519302; called by muse, mutect2, varscan2
- RBCK1 | c.7G>A p.E3K (on ENST00000356286 / NM_031229.4; = p.R9Q on NM_006462.6) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV62291811; called by muse, mutect2, varscan2
- RBFA | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV51533015; called by muse, mutect2, varscan2
- RFWD3 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 96/227 reads (42%) | catalogued as COSV63097379; called by muse, mutect2, varscan2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, mutect2, varscan2
- RMC1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 212/389 reads (54%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV52570863; called by muse, mutect2, varscan2
- RNF213 | c.8000C>G p.S2667C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60392181; called by muse, mutect2, varscan2
- RPS6KA3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV65387168; called by muse, mutect2, varscan2
- RSU1 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs1435351878, COSV61714742; called by muse, mutect2, varscan2
- SCN4A | c.4800C>A p.N1600K | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV71125911; called by muse, mutect2, varscan2
- SCYL3 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV63047449; called by muse, mutect2, varscan2
- SEMA5B | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV52092553; called by muse, mutect2, varscan2
- SETDB1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54990717; called by muse, mutect2, varscan2
- SIKE1 | c.522+1G>A p.X174_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV50258615, COSV50258619; called by muse, varscan2
- SIPA1 | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.628); catalogued as rs769162298, COSV58014023; called by muse, mutect2, varscan2
- SLC25A12 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV55531955, COSV55536460; called by muse, mutect2, varscan2
- SLC45A1 | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV57093506; called by muse, mutect2, varscan2
- SLC8A1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.693); catalogued as rs1315931415, COSV60473539; called by muse, mutect2, varscan2
- SLIT1 | c.2380A>C p.N794H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56584417; called by muse, mutect2, varscan2
- SMAD3 | c.1093C>A p.Q365K | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV59281302; called by muse, mutect2, varscan2
- SMOC2 | c.1001C>T p.S334L (on ENST00000356284 / NM_001166412.2; = p.S345L on NM_022138.3) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.26); PolyPhen benign (0.311); catalogued as rs774971325, COSV62434821; called by muse, mutect2, varscan2
- SNRPB | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60015074; called by muse, mutect2, varscan2
- SPANXN2 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.736); catalogued as COSV65127877; called by muse, mutect2, varscan2
- SPIDR | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as COSV52371781; called by muse, mutect2, varscan2
- STAG2 | c.820-2A>C p.X274_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV54352773; called by muse, mutect2, varscan2
- SYN2 | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV70285002; called by muse, mutect2, varscan2
- TDRD6 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60174343; called by muse, mutect2, varscan2
- TDRD6 | c.5605C>G p.L1869V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV60174349; called by muse, mutect2, varscan2
- TESMIN | c.145T>A p.F49I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.099); catalogued as COSV54831649; called by muse, mutect2, varscan2
- TLR7 | c.1133G>C p.R378T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV66123720; called by muse, mutect2, varscan2
- TLR7 | c.1643A>T p.D548V | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66123723; called by muse, mutect2, varscan2
- TRAF6 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); catalogued as COSV61922078; called by muse, mutect2, varscan2
- TRAPPC13 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as COSV51549981; called by muse, mutect2, varscan2
- TRERF1 | c.1879G>C p.V627L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV61668196; called by muse, mutect2, varscan2
- TRPV6 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63890881; called by muse, mutect2, varscan2
- USP31 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54850118; called by muse, mutect2
- UTP20 | c.5001G>C p.Q1667H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); catalogued as COSV55373518, COSV55383962; called by muse, mutect2, varscan2
- UTP20 | c.6139C>T p.P2047S | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV55373530; called by muse, mutect2, varscan2
- WDR11 | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV54785891; called by muse, mutect2, varscan2
- WTAP | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs771975668, COSV61609863; called by muse, mutect2, varscan2
- XDH | c.3668G>A p.R1223H | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs762431704, COSV65147393; called by muse, mutect2, varscan2
- ZBTB2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs376506691; called by muse, mutect2, varscan2
- ZNF518A | c.4009C>T p.L1337F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60150566; called by muse, mutect2, varscan2
- ZNF589 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.258); catalogued as rs1559984172, COSV61220160; called by muse, mutect2, varscan2
- ZNF778 | c.1334G>C p.G445A | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60600727; called by muse, mutect2, varscan2
- ZRSR2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV57063852; called by muse, mutect2
- ZXDB | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV66492471; called by muse, mutect2, varscan2
- CD84 | c.837C>A p.Y279* (on ENST00000311224 / NM_001184879.2; = p.Y262* on NM_003874.4) | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- DHX30 | c.3192-17_3192-1del p.X1064_splice (on ENST00000445061 / NM_138615.3; = p.X1025_splice on NM_014966.3) | Splice Site (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- ELF3 | c.991_1001+6del p.X331_splice | Splice Site (DEL) | VAF 12/16 reads (75%) | called by mutect2, varscan2
- IGLV5-37 | c.184_200del p.G62Sfs*10 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- KDM6A | c.2266del p.A756Qfs*18 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- KLHDC7A | c.9_25del p.R4Gfs*81 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- LCAT | c.1021_1030del p.V341Pfs*66 | Frame Shift Del (DEL) | VAF 48/155 reads (31%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1057C>G p.P353A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUTM1 | c.2507G>A p.W836* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- SCAMP3 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 50/317 reads (16%) | called by muse, mutect2, varscan2
- TMED9 | c.37_53del p.R13Gfs*2 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- ZSWIM8 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- A2M | c.2934C>G p.V978= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV59383887; called by muse, mutect2, varscan2
- ALPK3 | c.3453C>T p.L1151= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1002162937; called by muse, mutect2
- AMT | c.198T>A p.T66= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV56469073; called by muse, mutect2, varscan2
- ANGEL1 | c.1065C>A p.G355= | Silent (SNP) | VAF 108/248 reads (44%) | catalogued as COSV51872119; called by muse, mutect2, varscan2
- ANKRD30A | c.2682C>A p.A894= (on ENST00000611781; = p.A838= on NM_052997.2) | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV64605887, COSV64622853; called by muse, mutect2, varscan2
- BIRC6 | c.1149T>C p.D383= | Silent (SNP) | VAF 91/229 reads (40%) | catalogued as COSV70196599; called by muse, mutect2, varscan2
- CDK11A | c.1992C>T p.F664= (on ENST00000378633 / NM_001313896.2; = p.F661= on NM_024011.4) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV52306925; called by muse, mutect2
- CHAT | c.2028T>C p.N676= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as COSV60321408; called by muse, mutect2, varscan2
- CLTC | c.2598T>A p.I866= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52245556; called by muse, mutect2, varscan2
- CLVS2 | c.210C>G p.R70= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV51567812; called by muse, mutect2, varscan2
- CTNND2 | c.2937G>A p.K979= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV58871615; called by muse, mutect2, varscan2
- DCST1 | c.615G>T p.T205= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs771996479, COSV55058542, COSV55062260; called by muse, mutect2, varscan2
- DLGAP2 | c.2475G>T p.G825= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV70102879; called by muse, mutect2, varscan2
- DNAH10 | c.6399C>T p.D2133= (on ENST00000409039; = p.D2072= on NM_207437.3) | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV68989432; called by muse, mutect2, varscan2
- DNM2 | c.381A>G p.P127= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV58957966; called by muse, mutect2, varscan2
- DOP1B | c.6720C>T p.I2240= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV67690688; called by muse, varscan2
- DOP1B | c.6741C>T p.F2247= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV67690691; called by muse, varscan2
- DZIP3 | c.3282A>G p.K1094= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV64311364; called by muse, mutect2, varscan2
- ESPL1 | c.1839G>A p.L613= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs772945895, COSV57757951; called by muse, mutect2, varscan2
- FAF1 | c.1761G>A p.E587= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV65642879; called by muse, mutect2, varscan2
- FANCA | c.1305C>G p.R435= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV66880809; called by muse, mutect2, varscan2
- FAT2 | c.2403C>T p.S801= | Silent (SNP) | VAF 49/61 reads (80%) | catalogued as rs1207490087, COSV55815123; called by muse, mutect2, varscan2
- FGL1 | c.213C>T p.V71= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs760210271, COSV67712002; called by muse, mutect2, varscan2
- FLNB | c.3987T>C p.S1329= | Silent (SNP) | VAF 57/103 reads (55%) | catalogued as COSV55872966; called by muse, mutect2, varscan2
- FZD3 | c.333G>A p.S111= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs759657609, COSV53534669; called by muse, mutect2, varscan2
- GLMN | c.171C>T p.I57= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV64859993; called by muse, mutect2, varscan2
- ISY1 | c.591G>A p.L197= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV56442775; called by muse, mutect2
- KRT39 | c.1053G>A p.L351= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as COSV62916924; called by muse, mutect2, varscan2
- LCA5L | c.1017T>C p.H339= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55744190; called by muse, mutect2, varscan2
- LDLRAP1 | c.813C>T p.V271= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- LHX4 | c.129G>A p.L43= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV55377523; called by muse, mutect2, varscan2
- LRIT3 | c.855C>A p.I285= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV59983528; called by muse, mutect2
- MEP1B | c.2061C>T p.S687= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52496104; called by muse, mutect2
- MTHFD2 | c.249C>G p.S83= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV51201066; called by muse, mutect2, varscan2
- MUC17 | c.11160C>G p.V3720= | Silent (SNP) | VAF 84/196 reads (43%) | catalogued as COSV60282301; called by muse, mutect2, varscan2
- MYBL2 | c.513T>C p.A171= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV53828349; called by muse, mutect2, varscan2
- MYO1C | c.1308C>T p.F436= (on ENST00000648651 / NM_001080779.2; = p.F401= on NM_033375.5) | Silent (SNP) | VAF 33/47 reads (70%) | catalogued as COSV62998581, COSV63000372; called by muse, mutect2, varscan2
- NFKB2 | c.537A>G p.K179= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs774146275, COSV51874793; called by muse, mutect2, varscan2
- NYNRIN | c.4026C>T p.S1342= | Silent (SNP) | VAF 99/223 reads (44%) | catalogued as COSV66841471; called by muse, mutect2, varscan2
- OR6B1 | c.438T>A p.L146= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV68769875; called by muse, mutect2, varscan2
- PIK3C2B | c.2886C>T p.L962= | Silent (SNP) | VAF 163/189 reads (86%) | catalogued as COSV65809728; called by muse, mutect2, varscan2
- PIR | c.66G>A p.A22= | Silent (SNP) | VAF 106/238 reads (45%) | catalogued as rs370522973, COSV62916272; called by muse, mutect2, varscan2
- PNLIP | c.33G>A p.L11= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV65039881; called by muse, mutect2, varscan2
- PRAMEF6 | c.1368C>T p.D456= | Silent (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- PSMD12 | c.129C>T p.V43= | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as COSV62065215; called by muse, mutect2, varscan2
- RREB1 | c.2070G>T p.L690= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV58554825; called by muse, mutect2, varscan2
- SEMA4C | c.12C>T p.H4= | Silent (SNP) | VAF 61/158 reads (39%) | catalogued as COSV59689919; called by muse, mutect2, varscan2
- SHE | c.1122C>A p.A374= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as COSV59071063, COSV59072835; called by muse, varscan2
- SLC17A9 | c.1077C>T p.N359= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as COSV64848063; called by muse, mutect2
- SLC22A23 | c.1617G>T p.A539= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV66676852; called by muse, mutect2, varscan2
- SLC30A4 | c.303G>A p.Q101= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV56005363; called by muse, mutect2, varscan2
- SLC9A3 | c.1956C>T p.I652= | Silent (SNP) | VAF 71/91 reads (78%) | catalogued as COSV53799544; called by muse, mutect2, varscan2
- SMG9 | c.435T>C p.P145= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV54215985; called by muse, mutect2, varscan2
- SPAG17 | c.1005G>A p.E335= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV60454547; called by muse, mutect2, varscan2
- SULT1C4 | c.378A>T p.L126= | Silent (SNP) | VAF 107/253 reads (42%) | catalogued as COSV55597391; called by muse, mutect2, varscan2
- TNRC6A | c.2607C>T p.A869= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100170282, COSV59362090; called by muse, mutect2
- TRIM58 | c.615G>A p.E205= | Silent (SNP) | VAF 46/55 reads (84%) | catalogued as rs759710514, COSV63571854; called by muse, mutect2, varscan2
- TTC21A | c.3891C>T p.L1297= | Silent (SNP) | VAF 48/75 reads (64%) | catalogued as rs1269941383, COSV56187133, COSV56187416; called by muse, mutect2, varscan2
- TTLL2 | c.1626G>C p.L542= | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as COSV53442856; called by muse, mutect2, varscan2
- UBE2L6 | c.429C>T p.F143= | Silent (SNP) | VAF 76/182 reads (42%) | catalogued as COSV54702426; called by muse, mutect2, varscan2
- UBR2 | c.2937T>G p.A979= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV65749172; called by muse, mutect2, varscan2
- UBR4 | c.5238G>A p.Q1746= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV64384047; called by muse, mutect2, varscan2
- UTP4 | c.1686T>C p.D562= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV58732225; called by muse, mutect2, varscan2
- UTRN | c.60T>C p.D20= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV62329833; called by muse, mutect2, varscan2
- ZNF320 | c.978G>A p.E326= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV67087700; called by muse, mutect2, varscan2
- BCL2L13 | c.600+4414G>A | Intron (SNP) | VAF 37/129 reads (29%) | catalogued as COSV100456318; called by muse, mutect2, varscan2
- CCDC18 | c.-3+233C>T | Intron (SNP) | VAF 21/30 reads (70%) | catalogued as COSV58142514; called by muse, mutect2, varscan2
- DBNDD1 | c.32-602A>C | Intron (SNP) | VAF 40/101 reads (40%) | catalogued as COSV50021889; called by muse, mutect2, varscan2
- DLG2 | c.205-65809G>C | Intron (SNP) | VAF 42/202 reads (21%) | catalogued as COSV54675090, COSV54675674; called by muse, mutect2, varscan2
- KAT6A | c.1483-1777C>G | Intron (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55910894; called by muse, mutect2, varscan2
- KIR3DX1 | n.384C>T | RNA (SNP) | VAF 28/71 reads (39%) | catalogued as rs371922853, COSV55597371, COSV55600351; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1249T>C | RNA (SNP) | VAF 74/147 reads (50%) | called by muse, mutect2, varscan2
- SSPOP | n.4246C>T | RNA (SNP) | VAF 3/38 reads (8%) | catalogued as rs866289293; called by muse, mutect2
- TMED2 | c.-2C>A | 5'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99147878; called by muse, mutect2, varscan2
